Somatic mutation profile of cancer-model specimen HCM-SANG-0304-C15-85A (3D Organoid; aliquot HCM-SANG-0304-C15-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-SANG-0304-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0304-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1cb6500-3b0d-4341-9fa3-389c78ca3fd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0304-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0304-C15-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5495f8d8-b1bc-4879-822c-cae92b047269

The open-access MAF lists 158 somatic variants for this specimen: 103 protein-altering or splice-affecting, 43 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 43, Intron 8, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 3, RNA 3, Splice Region 3, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 447/449 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SLC2A2 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs121909741, CM941278; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- SLC3A1 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 26/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201502095, CM972932, COSV53225385; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS18 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 192/409 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327426602, COSV51402426; called by muse, mutect2, varscan2
- AFAP1 | c.1588_1589del p.L530Efs*54 | Frame Shift Del (DEL) | VAF 115/346 reads (33%) | catalogued as rs1247828022; called by pindel, varscan2
- BEST4 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100943989; called by muse, mutect2, varscan2
- C8orf88 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs1173536954; called by muse, mutect2, varscan2
- CERCAM | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 112/363 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1244088649, COSV65711130; called by muse, mutect2, varscan2
- CNTNAP4 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs528691365, COSV56669638; called by muse, mutect2, varscan2
- CROCC | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.155); catalogued as rs773990250; called by muse, mutect2, varscan2
- CYP20A1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs777630188, COSV61909099; called by muse, mutect2
- DACT1 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.51); catalogued as rs1184871353, COSV100241802; called by muse, mutect2, varscan2
- DEDD2 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs771045520, COSV60141481; called by muse, mutect2, varscan2
- DMXL2 | c.2981C>T p.T994M | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770583176, COSV99196165; called by muse, mutect2
- DPP3 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 319/320 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1471967449, COSV64757609; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs144947064; called by muse, mutect2, varscan2
- EMSY | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs746284940; called by muse, mutect2, varscan2
- FAM71E2 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1283835392, COSV52772621; called by muse, mutect2, varscan2
- FLG | c.6809C>A p.S2270Y | Missense Mutation (SNP) | VAF 441/1007 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1359253104, COSV64236632; called by muse, mutect2, varscan2
- FZD2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV59528447; called by muse, mutect2
- GPR88 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 104/205 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as rs1012541366; called by muse, mutect2, varscan2
- H2BC17 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 108/356 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV58154113; called by muse, mutect2
- HERC1 | c.14071C>T p.R4691* | Nonsense Mutation (SNP) | VAF 41/87 reads (47%) | catalogued as rs951302383, COSV71246789; called by muse, mutect2, varscan2
- IGFN1 | c.2372C>T p.T791M (on ENST00000295591 / NM_001367841.1; = p.T3248M on NM_001164586.2) | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs372527310; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1289G>A p.R430Q (on ENST00000439118 / NM_001008949.3; = p.R438Q on NM_178495.6) | Missense Mutation (SNP) | VAF 209/219 reads (95%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs745512936; called by muse, mutect2, varscan2
- KCNJ12 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs781849043; called by muse, mutect2, varscan2
- KLKB1 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.45); catalogued as COSV52994496; called by muse, mutect2, varscan2
- KNDC1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 104/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769679687; called by muse, mutect2, varscan2
- LTBP4 | c.1201G>A p.V401M (on ENST00000308370 / NM_001042544.1; = p.V364M on NM_003573.2) | Missense Mutation (SNP) | VAF 20/465 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52576399; called by muse, mutect2
- MAGEE1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs782292584, COSV100819400; called by muse, mutect2, varscan2
- MAP2K7 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 177/178 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101208995; called by muse, mutect2, varscan2
- MEGF11 | c.1572G>A p.P524= | Splice Region (SNP) | VAF 15/146 reads (10%) | catalogued as rs972101500, COSV99986630; called by muse, mutect2
- MOV10L1 | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs372963947; called by muse, mutect2, varscan2
- NOTCH3 | c.5542C>A p.R1848S | Missense Mutation (SNP) | VAF 127/572 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54640321, COSV54641237; called by muse, mutect2, varscan2
- NUP62 | c.1417C>A p.Q473K | Missense Mutation (SNP) | VAF 231/481 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs1368744623; called by muse, mutect2, varscan2
- OR4A47 | c.527dup p.C177Lfs*2 | Frame Shift Ins (INS) | VAF 168/251 reads (67%) | catalogued as rs753340791; called by mutect2, pindel, varscan2
- PCDHA8 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 98/202 reads (49%) | catalogued as rs782317830, COSV100970840; called by muse, mutect2
- PCDHGA4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 132/266 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53917873; called by muse, mutect2, varscan2
- PDZD2 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs141793371; called by muse, mutect2, varscan2
- PTGDR | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV100035596; called by muse, mutect2, varscan2
- PTPRJ | c.2839C>A p.L947I | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.55); catalogued as rs1565326189; called by muse, mutect2
- RALGAPA2 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 254/1207 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs776538646, COSV52493267; called by muse, mutect2, varscan2
- REM1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 197/345 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs749761528, COSV52429909; called by muse, mutect2, varscan2
- RFLNA | c.478C>T p.R160C (on ENST00000546355 / NM_001365156.1; = p.R79C on NM_181709.4) | Missense Mutation (SNP) | VAF 282/549 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs763677847; called by muse, mutect2, varscan2
- RSC1A1 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | catalogued as rs775726411; called by muse, mutect2
- RTP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 140/323 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as rs779758552, COSV64078993; called by muse, mutect2, varscan2
- SHROOM1 | c.2432G>A p.R811H (on ENST00000378679 / NM_001172700.2; = p.R806H on NM_133456.2) | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs1374976897; called by muse, varscan2
- SLC34A2 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 304/304 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327576349; called by muse, mutect2, varscan2
- SLC36A2 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 211/393 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs201656264; called by muse, mutect2, varscan2
- SYNE1 | c.16294C>T p.R5432W (on ENST00000367255 / NM_182961.4; = p.R5361W on NM_033071.3) | Missense Mutation (SNP) | VAF 159/275 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs575137601; called by muse, mutect2, varscan2
- TFAP2A | c.128G>A p.S43N (on ENST00000482890; = p.S35N on NM_001032280.3) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.914); catalogued as COSV60236797; called by muse, mutect2, varscan2
- TJP2 | c.1320-1G>A p.X440_splice | Splice Site (SNP) | VAF 65/500 reads (13%) | catalogued as rs763103460; called by muse, mutect2, varscan2
- USH2A | c.12794G>T p.G4265V | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs769342088; called by muse, mutect2, varscan2
- XDH | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 564/586 reads (96%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as rs61731083; called by muse, mutect2, varscan2
- ZDHHC8 | c.1368del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | catalogued as rs752072853; called by mutect2, pindel, varscan2
- ZNF189 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 50/264 reads (19%) | catalogued as rs1415450023, COSV52274769; called by muse, mutect2, varscan2
- ZNF492 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 118/339 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs1263554052; called by muse, mutect2, varscan2
- ABCA13 | c.4832A>T p.D1611V | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2
- ABCA9 | c.4722T>G p.V1574= | Splice Region (SNP) | VAF 52/191 reads (27%) | called by muse, mutect2, varscan2
- ANKS1B | c.725T>G p.V242G | Missense Mutation (SNP) | VAF 114/333 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ARID4B | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 253/527 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ARNTL2 | c.1093A>C p.N365H | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRNL1 | c.1628A>T p.D543V | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDHR1 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.936); called by muse, mutect2
- COL2A1 | c.2779G>A p.G927S | Missense Mutation (SNP) | VAF 19/628 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL5A3 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2
- EIF2D | c.56+2T>C p.X19_splice | Splice Site (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- ELAVL4 | c.472A>C p.I158L | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ENO3 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 87/638 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ETF1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FRRS1L | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCN1 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 38/677 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2
- HECTD2 | c.1545C>A p.N515K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- IL9R | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 329/330 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- IRX1 | c.1382A>T p.D461V | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ITGBL1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ITIH6 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- JAGN1 | c.22_40del p.R8Afs*16 | Frame Shift Del (DEL) | VAF 20/204 reads (10%) | called by mutect2, pindel
- MALRD1 | c.4833G>T p.Q1611H | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MRAP | c.374A>C p.Q125P | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- MROH5 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- MYEF2 | c.1296T>A p.F432L | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NAV1 | c.4035G>T p.M1345I | Missense Mutation (SNP) | VAF 363/364 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NT5DC1 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- P4HA3 | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 172/173 reads (99%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR1A | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PUS10 | c.186A>C p.E62D | Missense Mutation (SNP) | VAF 181/190 reads (95%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RET | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- RNF19B | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RSPH9 | c.660C>A p.D220E | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A17 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SLITRK1 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SNX14 | c.552G>C p.V184= (on ENST00000314673 / NM_001350535.1; = p.V140= on NM_020468.5 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 32/82 reads (39%) | called by muse, varscan2
- TFDP1 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 207/208 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TMEM205 | c.175del p.H59Tfs*36 | Frame Shift Del (DEL) | VAF 116/471 reads (25%) | called by mutect2, pindel, varscan2
- TTC28 | c.2254_2258del p.L752Sfs*18 | Frame Shift Del (DEL) | VAF 166/349 reads (48%) | called by mutect2, pindel, varscan2
- TVP23A | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- USH2A | c.4627+1G>T p.X1543_splice (on ENST00000307340 / NM_206933.4; = p.G1543V on NM_007123.6) | Splice Site (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- USP32 | c.4804G>A p.V1602M | Missense Mutation (SNP) | VAF 98/100 reads (98%) | SIFT deleterious (0.03); PolyPhen benign (0.131); called by muse, varscan2
- WDR81 | c.1140C>G p.H380Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WFDC2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 29/787 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.294); called by muse, mutect2
- XRN1 | c.1945A>G p.I649V | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF322 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 223/478 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- AKT2 | c.597C>T p.T199= | Silent (SNP) | VAF 176/877 reads (20%) | catalogued as rs538944575; called by muse, mutect2, varscan2
- CCDC60 | c.768T>A p.S256= | Silent (SNP) | VAF 100/329 reads (30%) | called by muse, mutect2, varscan2
- CDK16 | c.885C>T p.N295= | Silent (SNP) | VAF 100/101 reads (99%) | catalogued as rs1470221384, COSV99331675; called by muse, mutect2, varscan2
- CHD6 | c.8058C>T p.A2686= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as rs142643615; called by muse, mutect2, varscan2
- CLMN | c.2568G>A p.T856= | Silent (SNP) | VAF 76/249 reads (31%) | catalogued as rs142393118; called by muse, mutect2, varscan2
- CTDNEP1 | c.696C>T p.S232= | Silent (SNP) | VAF 218/218 reads (100%) | catalogued as rs142077609; called by muse, mutect2, varscan2
- FAM83G | c.1071C>T p.V357= | Silent (SNP) | VAF 445/446 reads (100%) | catalogued as rs1567791186, COSV58762847; called by muse, mutect2, varscan2
- FRMPD3 | c.2115T>A p.G705= | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- GBP3 | c.972C>T p.A324= | Silent (SNP) | VAF 327/703 reads (47%) | catalogued as rs1049271646; called by muse, mutect2, varscan2
- GTF3C2 | c.1035C>T p.A345= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as rs753324970, COSV53125037; called by muse, mutect2, varscan2
- H2BC17 | c.333C>T p.A111= | Silent (SNP) | VAF 106/354 reads (30%) | catalogued as rs775569027, COSV58152634; called by muse, mutect2
- HAPLN4 | c.534C>T p.F178= | Silent (SNP) | VAF 95/208 reads (46%) | called by muse, mutect2, varscan2
- LRRC69 | c.1011T>A p.R337= | Silent (SNP) | VAF 6/149 reads (4%) | called by muse, mutect2
- LRRK2 | c.5772T>C p.L1924= | Silent (SNP) | VAF 34/528 reads (6%) | called by muse, mutect2
- MAGEB2 | c.405A>G p.G135= | Silent (SNP) | VAF 112/112 reads (100%) | called by muse, mutect2, varscan2
- MUC16 | c.23478T>G p.A7826= | Silent (SNP) | VAF 117/117 reads (100%) | catalogued as rs765190962, COSV67487937; called by muse, mutect2, varscan2
- MVP | c.2637C>A p.A879= | Silent (SNP) | VAF 95/169 reads (56%) | called by muse, mutect2, varscan2
- NHSL1 | c.2565G>T p.G855= | Silent (SNP) | VAF 137/256 reads (54%) | called by muse, mutect2, varscan2
- NKX2-4 | c.894G>A p.Q298= | Silent (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- NLRC5 | c.1386G>A p.E462= | Silent (SNP) | VAF 100/333 reads (30%) | called by muse, mutect2, varscan2
- PASK | c.3693G>T p.L1231= | Silent (SNP) | VAF 279/434 reads (64%) | called by muse, mutect2, varscan2
- PCDHA9 | c.144C>T p.I48= | Silent (SNP) | VAF 193/459 reads (42%) | called by muse, mutect2, varscan2
- PCNX2 | c.6099C>T p.F2033= | Silent (SNP) | VAF 322/702 reads (46%) | catalogued as rs751216591, COSV50799095; called by muse, mutect2, varscan2
- PINLYP | c.102G>A p.A34= | Silent (SNP) | VAF 145/318 reads (46%) | catalogued as rs764456539; called by muse, mutect2
- PKD1 | c.11745C>G p.A3915= (on ENST00000262304 / NM_001009944.3; = p.A3914= on NM_000296.4) | Silent (SNP) | VAF 155/299 reads (52%) | catalogued as rs755022166, CD1210725; called by muse, mutect2, varscan2
- RASGRF1 | c.174G>A p.S58= | Silent (SNP) | VAF 176/388 reads (45%) | catalogued as rs899001969, COSV69176768; called by muse, mutect2, varscan2
- RUFY3 | c.429C>T p.A143= | Silent (SNP) | VAF 69/69 reads (100%) | catalogued as rs139284262; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIPA1L3 | c.2280C>T p.N760= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as rs201959023; called by muse, mutect2, varscan2
- STK3 | c.111T>C p.S37= | Silent (SNP) | VAF 87/127 reads (69%) | called by muse, mutect2, varscan2
- SYNE3 | c.2082G>A p.V694= | Silent (SNP) | VAF 73/221 reads (33%) | catalogued as rs752180221; called by muse, mutect2, varscan2
- TBC1D2 | c.1569C>T p.D523= | Silent (SNP) | VAF 96/243 reads (40%) | catalogued as rs148036923, COSV100579775; called by muse, mutect2, varscan2
- TENM4 | c.978G>A p.P326= | Silent (SNP) | VAF 234/235 reads (100%) | catalogued as rs1043775367; called by muse, mutect2, varscan2
- THBS2 | c.171C>T p.F57= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as rs139930955; called by muse, mutect2
- TOX3 | c.474C>A p.V158= | Silent (SNP) | VAF 172/476 reads (36%) | called by muse, mutect2, varscan2
- TRMT5 | c.468C>T p.L156= | Silent (SNP) | VAF 93/255 reads (36%) | catalogued as rs775431970; called by muse, mutect2, varscan2
- TTC31 | c.15A>G p.P5= | Silent (SNP) | VAF 36/486 reads (7%) | catalogued as rs369017993; called by muse, mutect2
- WDR93 | c.411G>A p.A137= | Silent (SNP) | VAF 165/357 reads (46%) | catalogued as rs377345020; called by muse, mutect2, varscan2
- WTIP | c.462C>T p.G154= | Silent (SNP) | VAF 44/173 reads (25%) | called by muse, mutect2, varscan2
- XRN1 | c.4185A>G p.G1395= | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- ZNF594 | c.1353T>C p.H451= | Silent (SNP) | VAF 14/433 reads (3%) | called by muse, mutect2
- ZNF605 | c.1545C>A p.A515= | Silent (SNP) | VAF 7/157 reads (4%) | called by muse, mutect2
- ZNF71 | c.1230C>T p.Y410= | Silent (SNP) | VAF 180/431 reads (42%) | catalogued as rs1326664150; called by muse, mutect2, varscan2
- ZNF771 | c.252G>A p.T84= | Silent (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- AGAP14P | n.1254C>A | RNA (SNP) | VAF 383/1352 reads (28%) | called by muse, varscan2
- AGPAT2 | c.316+23C>A | Intron (SNP) | VAF 110/361 reads (30%) | called by muse, mutect2, varscan2
- AP001122.1 | n.465C>T | RNA (SNP) | VAF 174/175 reads (99%) | catalogued as rs565802031; called by muse, mutect2, varscan2
- BCL11A | c.386-6393G>T | Intron (SNP) | VAF 88/279 reads (32%) | catalogued as COSV100185034; called by muse, mutect2, varscan2
- C16orf70 | c.661+216C>T | Intron (SNP) | VAF 76/208 reads (37%) | catalogued as rs755742145; called by muse, mutect2, varscan2
- GRM8 | c.727+48380C>T | Intron (SNP) | VAF 10/241 reads (4%) | catalogued as rs1414578610, COSV58808115; called by muse, mutect2
- NDUFA5 | c.66+381T>G | Intron (SNP) | VAF 317/319 reads (99%) | called by muse, mutect2, varscan2
- NTPCR | c.505-1808T>C | Intron (SNP) | VAF 13/196 reads (7%) | called by muse, mutect2
- RPS6KL1 | c.*266G>A | 3'UTR (SNP) | VAF 192/301 reads (64%) | catalogued as rs760993170; called by muse, mutect2, varscan2
- SSUH2 | n.431G>A | RNA (SNP) | VAF 13/29 reads (45%) | catalogued as rs1484288158; called by muse, mutect2, varscan2
- TMTC4 | c.-54-1597C>T | Intron (SNP) | VAF 23/57 reads (40%) | catalogued as rs768033673; called by muse, mutect2, varscan2
- UAP1L1 | c.495-24C>T | Intron (SNP) | VAF 125/285 reads (44%) | called by muse, mutect2, varscan2
